Somatic mutation profile of tumor specimen ALCH-B1RI-TTP1-A (aliquot ALCH-B1RI-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1RI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.8 years (25,510 days).
Specimen ALCH-B1RI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d851010-5f35-49c0-b9a1-1efdba083394.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RI-NB1-A (Blood Derived Normal), aliquot ALCH-B1RI-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4de172c9-d8b9-4943-bbbb-e77e337c1ad7

The open-access MAF lists 246 somatic variants for this specimen: 162 protein-altering or splice-affecting, 52 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 52, Intron 13, RNA 9, Nonsense Mutation 6, Frame Shift Del 6, 3'UTR 6, Splice Site 3, 5'UTR 2, Translation Start Site 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 68/233 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1553567409, COSV51839806, COSV99330521; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- STK11 | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 30/69 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM022255, CM1510368, COSV58820077, COSV58827670; called by muse, mutect2, varscan2
- ABCA13 | c.12874G>T p.D4292Y | Missense Mutation (SNP) | VAF 72/285 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs367684378, COSV68948010; called by muse, mutect2, varscan2
- ADAMTS12 | c.2302G>T p.A768S | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100710660; called by muse, mutect2, varscan2
- AFP | c.1811G>T p.R604L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs761427886, COSV99890003; called by muse, mutect2, varscan2
- AGMO | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764537420, COSV61105202; called by muse, mutect2, varscan2
- ARMCX1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV65704865; called by muse, mutect2, varscan2
- ASAH2 | c.1370C>A p.A457E | Missense Mutation (SNP) | VAF 60/405 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907585652; called by muse, mutect2, varscan2
- ASTL | c.764G>T p.W255L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as COSV100668398; called by muse, mutect2, varscan2
- CDC14B | c.623A>G p.Y208C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs1327429044; called by muse, mutect2, varscan2
- CDH9 | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV50258828; called by muse, mutect2, varscan2
- CHST1 | c.813G>T p.Q271H | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV57325586; called by muse, mutect2, varscan2
- CLDN2 | c.422A>G p.H141R | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs1226193123; called by muse, mutect2, varscan2
- COBL | c.2684G>T p.G895V | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs774862992; called by muse, mutect2, varscan2
- COL15A1 | c.3559G>A p.D1187N | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs186296440, COSV66643602; called by muse, mutect2, varscan2
- COL20A1 | c.3567C>T p.G1189= | Splice Region (SNP) | VAF 77/262 reads (29%) | catalogued as rs746683676, COSV58920067; called by muse, mutect2, varscan2
- CSPG4 | c.3135C>G p.S1045R | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.626); catalogued as COSV57900329; called by muse, mutect2, varscan2
- ERBB4 | c.3725A>T p.Y1242F | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100722631, COSV61476936; called by muse, mutect2, varscan2
- ERICH3 | c.2497C>G p.P833A | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV58604561; called by muse, mutect2, varscan2
- FAM160A2 | c.1919G>T p.G640V (on ENST00000449352 / NM_001098794.2; = p.G654V on NM_032127.4) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1168019353; called by muse, mutect2, varscan2
- FAM160A2 | c.1918G>A p.G640R (on ENST00000449352 / NM_001098794.2; = p.G654R on NM_032127.4) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as rs775778791; called by muse, mutect2, varscan2
- FAM205A | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 79/339 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV101113023; called by muse, mutect2, varscan2
- FAM47B | c.1627C>A p.R543S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV100264435, COSV61452705; called by mutect2, varscan2
- FLG | c.1363C>A p.R455S | Missense Mutation (SNP) | VAF 153/425 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs757922040, COSV100911849; called by muse, mutect2, varscan2
- FURIN | c.829G>T p.G277W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51579051; called by muse, mutect2, varscan2
- GBP4 | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100864314; called by muse, mutect2, varscan2
- GRB7 | c.78del p.T27Lfs*13 | Frame Shift Del (DEL) | VAF 32/161 reads (20%) | catalogued as rs1277370350; called by mutect2, pindel, varscan2
- IGFBP1 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51875091; called by muse, mutect2, varscan2
- IGKV1-12 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1259942444; called by muse, mutect2, varscan2
- KRTAP8-1 | c.25G>C p.A9P | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.31); catalogued as COSV61598055; called by muse, mutect2, varscan2
- LUZP4 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV64219781; called by muse, varscan2
- NEXMIF | c.3728G>T p.R1243L | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); catalogued as COSV50033492; called by muse, mutect2, varscan2
- NR0B2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370959977, COSV54260122; called by muse, mutect2, varscan2
- OR2A2 | c.817C>A p.L273M | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101286681; called by muse, mutect2, varscan2
- OR2A25 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68717382; called by muse, mutect2, varscan2
- OR51F1 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as rs749009953; called by muse, mutect2, varscan2
- OTOGL | c.6044T>C p.V2015A (on ENST00000547103; = p.V2006A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs539458827; called by muse, mutect2, varscan2
- P2RY8 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184019; called by muse, mutect2, varscan2
- PRAMEF18 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 54/554 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1484230227; called by muse, mutect2
- PTPN23 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs990572884; called by muse, mutect2, varscan2
- RSL1D1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100852000, COSV100852017; called by muse, mutect2, varscan2
- SAMD9L | c.1899G>T p.R633S | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV59084693; called by muse, mutect2, varscan2
- SERPINA12 | c.1161C>G p.D387E | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs961390313; called by muse, mutect2, varscan2
- SLC5A11 | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 84/293 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61740905; called by muse, mutect2, varscan2
- SLCO1B1 | c.1748-1G>A p.X583_splice | Splice Site (SNP) | VAF 35/141 reads (25%) | catalogued as rs1176615755; called by muse, mutect2, varscan2
- SLITRK2 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59425233, COSV59426746; called by muse, mutect2, varscan2
- SPATC1L | c.491C>A p.S164* (on ENST00000291672 / NM_001142854.2; = p.S10* on NM_032261.5) | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV52433396; called by muse, mutect2, varscan2
- SPG11 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM111391, COSV55998922; called by muse, varscan2
- STK31 | c.1638C>A p.D546E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV63456447; called by muse, mutect2, varscan2
- TAS2R38 | c.512C>A p.T171K | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV71885531; called by muse, mutect2, varscan2
- TMA16 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs780905691; called by muse, mutect2, varscan2
- TNN | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV53422228; called by muse, mutect2, varscan2
- TPRG1 | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 110/391 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV61465715; called by muse, mutect2, varscan2
- TRPA1 | c.1562C>A p.A521E | Missense Mutation (SNP) | VAF 189/513 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139821338; called by muse, mutect2, varscan2
- TRPM7 | c.3361G>T p.A1121S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as COSV100540192; called by muse, mutect2, varscan2
- WDR93 | c.410C>A p.A137E | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV51530469; called by muse, mutect2, varscan2
- ZNF71 | c.1316G>T p.R439M | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV60146961; called by muse, mutect2, varscan2
- ACOD1 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ACSM2B | c.1658C>A p.T553N | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ADAM23 | c.1529T>C p.V510A | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- AMPH | c.811C>A p.P271T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ANGPT1 | c.860C>A p.A287E | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- APOBEC4 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ARHGAP32 | c.4418A>T p.Y1473F (on ENST00000310343 / NM_001378025.1; = p.Y1124F on NM_014715.4) | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARR3 | c.702G>T p.Q234H | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARRB1 | c.547A>T p.T183S | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BBS9 | c.1108A>G p.N370D | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by mutect2, varscan2
- BCORL1 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 60/207 reads (29%) | called by muse, mutect2, varscan2
- BEND5 | c.746-1G>C p.X249_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2
- CACNA1G | c.1450C>A p.R484S | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1H | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC33 | c.1328C>G p.A443G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDC5L | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.137); called by muse, varscan2
- CDC5L | c.864_871del p.F288Lfs*28 | Frame Shift Del (DEL) | VAF 60/156 reads (38%) | called by pindel, varscan2
- CFAP57 | c.3609C>G p.I1203M (on ENST00000372492 / NM_001378189.1; = p.I1236M on NM_001195831.3) | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CSMD2 | c.6840del p.I2281Sfs*4 | Frame Shift Del (DEL) | VAF 38/132 reads (29%) | called by mutect2, varscan2
- DLG3 | c.1275G>T p.E425D (on ENST00000374360 / NM_021120.4; = p.E88D on NM_020730.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2
- DLL1 | c.1162G>T p.G388W | Missense Mutation (SNP) | VAF 144/357 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERGIC3 | c.1016+1G>T p.X339_splice | Splice Site (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- EVI5 | c.1401G>T p.L467F | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- FBN2 | c.8711G>A p.R2904K | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- FFAR3 | c.764C>A p.P255Q | Missense Mutation (SNP) | VAF 223/1658 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- FGD5 | c.923C>A p.A308E | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT14 | c.1621T>A p.S541T | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GLCCI1 | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.621); called by muse, varscan2
- GPNMB | c.1415del p.D472Vfs*11 (on ENST00000381990 / NM_001005340.2; = p.D460Vfs*11 on NM_002510.3) | Frame Shift Del (DEL) | VAF 42/180 reads (23%) | called by mutect2, pindel, varscan2
- HDGF | c.659A>T p.E220V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- HSD17B10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 94/328 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HSD17B3 | c.604A>T p.K202* | Nonsense Mutation (SNP) | VAF 134/390 reads (34%) | called by muse, mutect2, varscan2
- IGLC2 | c.141C>A p.S47R | Missense Mutation (SNP) | VAF 108/362 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by mutect2, varscan2
- IGSF22 | c.1796C>A p.A599E | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ITGA1 | c.3403G>A p.G1135R | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- KEAP1 | c.1089_1095del p.S363Rfs*35 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | called by mutect2, pindel, varscan2
- KIAA0825 | c.2733G>T p.K911N | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLK12 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 142/498 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LCOR | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LRRC4C | c.107T>A p.L36H | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MACC1 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MAGEB3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAPK8IP3 | c.2095G>T p.V699L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MEN1 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MMRN1 | c.2592C>A p.D864E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOGS | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MPO | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- MRPS27 | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.228); called by muse, varscan2
- MTMR1 | c.1829C>A p.P610H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- MTUS1 | c.3474C>A p.D1158E (on ENST00000262102 / NM_001363061.1; = p.D324E on NM_020749.4) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NAALADL1 | c.1081C>A p.R361S | Missense Mutation (SNP) | VAF 136/426 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- NEUROG1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 91/399 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NID2 | c.2614G>T p.G872C | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- NLGN2 | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOC4L | c.1056C>A p.D352E | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR10Q1 | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR1B1 | c.249G>T p.L83F | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- OR1L8 | c.159C>A p.N53K | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR6N1 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 105/229 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- P2RX2 | c.347C>G p.A116G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHA13 | c.2116G>C p.A706P | Missense Mutation (SNP) | VAF 91/372 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PCDHB11 | c.1471C>A p.L491I | Missense Mutation (SNP) | VAF 141/501 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PEX14 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 101/410 reads (25%) | called by muse, mutect2, varscan2
- PHACTR4 | c.972G>T p.E324D (on ENST00000373839 / NM_001350159.2; = p.E334D on NM_023923.4) | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- PIGC | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- POLR3B | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 70/268 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PPP1R12A | c.1924G>T p.A642S | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PPP4R3C | c.2308G>T p.G770C | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- PROX2 | c.656C>A p.A219E | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RABGGTB | c.569A>G p.H190R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCNN1A | c.1502G>T p.W501L | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SETDB1 | c.3029G>A p.G1010E | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGPP1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGPP1 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SHCBP1L | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC22A12 | c.344C>A p.P115Q | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK2 | c.138T>A p.C46* | Nonsense Mutation (SNP) | VAF 40/198 reads (20%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.467G>A p.C156Y | Missense Mutation (SNP) | VAF 43/131 reads (33%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNJ2 | c.2424G>C p.R808S | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TENM2 | c.850G>T p.A284S (on ENST00000518659 / NM_001122679.2; = p.A93S on NM_001080428.3) | Missense Mutation (SNP) | VAF 114/424 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TEX13C | c.1513C>A p.L505M | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- THSD7B | c.3139del p.G1047Dfs*20 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- TIAM1 | c.2534G>T p.S845I | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM185A | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 111/888 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TNN | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNS1 | c.4230G>C p.K1410N | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRBV28 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIL | c.1975G>T p.V659L | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM51 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRPM7 | c.3360G>A p.M1120I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TTN | c.6916C>A p.L2306I (on ENST00000591111; = p.L2260I on NM_003319.4) | Missense Mutation (SNP) | VAF 56/238 reads (24%) | PolyPhen benign (0.038); called by muse, varscan2
- TXK | c.394A>T p.I132F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.12805C>A p.P4269T | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13B | c.1869A>G p.I623M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); called by mutect2, varscan2
- WNK2 | c.1653G>T p.Q551H | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- WWC1 | c.2527A>T p.R843W | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- YPEL2 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by mutect2, varscan2
- ZBP1 | c.377T>A p.L126Q | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZBTB22 | c.1744A>T p.T582S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H12C | c.2396C>T p.S799F | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF157 | c.1079G>T p.C360F | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF536 | c.2003T>A p.L668Q | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ZNF595 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF607 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 37/138 reads (27%) | called by muse, mutect2, varscan2
- ACAD10 | c.438G>T p.R146= | Silent (SNP) | VAF 45/204 reads (22%) | called by muse, mutect2, varscan2
- ADGRG4 | c.2934C>T p.F978= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV54952961; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1509G>T p.A503= | Silent (SNP) | VAF 119/383 reads (31%) | called by muse, mutect2, varscan2
- CALHM2 | c.861C>T p.Y287= | Silent (SNP) | VAF 123/297 reads (41%) | catalogued as rs1290153147, COSV53296115; called by muse, mutect2, varscan2
- CCDC154 | c.96A>T p.G32= | Silent (SNP) | VAF 159/560 reads (28%) | called by muse, mutect2, varscan2
- CHST12 | c.201C>T p.D67= | Silent (SNP) | VAF 27/240 reads (11%) | catalogued as rs763991303; called by muse, mutect2, varscan2
- CNNM4 | c.706C>A p.R236= | Silent (SNP) | VAF 64/174 reads (37%) | catalogued as COSV65661428; called by muse, mutect2, varscan2
- COL20A1 | c.1923G>T p.R641= | Silent (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- DES | c.939C>A p.A313= | Silent (SNP) | VAF 144/548 reads (26%) | called by muse, mutect2, varscan2
- DISP3 | c.150C>A p.P50= | Silent (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- EDA2R | c.219C>A p.V73= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as COSV53630288; called by muse, mutect2, varscan2
- ESPL1 | c.4089G>T p.T1363= | Silent (SNP) | VAF 48/169 reads (28%) | called by muse, mutect2, varscan2
- FOXC2 | c.675C>A p.I225= | Silent (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- GLCCI1 | c.1539G>T p.A513= | Silent (SNP) | VAF 33/175 reads (19%) | catalogued as rs759778884, COSV56202750; called by muse, varscan2
- GRK1 | c.55C>A p.R19= | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- IFFO2 | c.1071C>T p.I357= | Silent (SNP) | VAF 69/219 reads (32%) | catalogued as rs922135272; called by muse, mutect2, varscan2
- IFNA10 | c.501C>A p.V167= | Silent (SNP) | VAF 46/232 reads (20%) | called by muse, mutect2, varscan2
- IGKV2D-26 | c.207C>T p.S69= | Silent (SNP) | VAF 86/270 reads (32%) | called by muse, mutect2, varscan2
- KCNC3 | c.1716C>T p.P572= | Silent (SNP) | VAF 67/210 reads (32%) | called by muse, mutect2, varscan2
- KRT10 | c.1449C>G p.S483= | Silent (SNP) | VAF 120/346 reads (35%) | called by muse, mutect2, varscan2
- LILRB5 | c.522G>T p.G174= | Silent (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- LRRN4CL | c.246G>T p.P82= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as rs766943738; called by muse, mutect2, varscan2
- LUC7L | c.954G>T p.R318= | Silent (SNP) | VAF 49/143 reads (34%) | called by muse, mutect2, varscan2
- MTOR | c.2580G>A p.K860= | Silent (SNP) | VAF 47/209 reads (22%) | catalogued as COSV63868180; called by muse, mutect2, varscan2
- MXRA5 | c.4083T>A p.T1361= | Silent (SNP) | VAF 36/105 reads (34%) | called by muse, mutect2, varscan2
- MYH7B | c.3643C>A p.R1215= | Silent (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- NLRC5 | c.1698G>C p.A566= | Silent (SNP) | VAF 82/243 reads (34%) | catalogued as rs1004722988; called by muse, mutect2, varscan2
- NLRP7 | c.1458G>A p.E486= | Silent (SNP) | VAF 52/176 reads (30%) | catalogued as COSV60170702; called by muse, mutect2, varscan2
- NNMT | c.159T>C p.G53= | Silent (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- NYAP1 | c.1875G>T p.A625= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as COSV55717700; called by muse, mutect2, varscan2
- OR11H12 | c.621C>A p.A207= | Silent (SNP) | VAF 45/141 reads (32%) | called by mutect2, varscan2
- OR2T4 | c.657C>G p.L219= | Silent (SNP) | VAF 59/257 reads (23%) | called by muse, mutect2, varscan2
- PCDHB1 | c.2142C>A p.V714= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV60633028; called by muse, mutect2, varscan2
- PFKFB1 | c.63C>T p.S21= | Silent (SNP) | VAF 39/167 reads (23%) | called by muse, mutect2, varscan2
- PXDNL | c.2187C>A p.A729= | Silent (SNP) | VAF 93/351 reads (26%) | catalogued as rs771551052; called by muse, mutect2, varscan2
- RAI1 | c.1476C>T p.P492= | Silent (SNP) | VAF 43/159 reads (27%) | catalogued as rs200887225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RASSF5 | c.417G>T p.L139= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- RB1CC1 | c.2238G>C p.S746= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV50273785; called by muse, mutect2, varscan2
- RBM10 | c.1080G>T p.L360= | Silent (SNP) | VAF 118/421 reads (28%) | called by muse, mutect2, varscan2
- RNF113A | c.30G>T p.A10= | Silent (SNP) | VAF 33/89 reads (37%) | called by muse, mutect2, varscan2
- SDHC | c.334C>T p.L112= | Silent (SNP) | VAF 70/291 reads (24%) | called by muse, mutect2, varscan2
- SLC36A1 | c.69G>A p.E23= | Silent (SNP) | VAF 18/242 reads (7%) | catalogued as rs1260523527; called by muse, mutect2
- SLC5A11 | c.1104C>G p.L368= | Silent (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- TCL1B | c.126G>T p.S42= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as rs563494390, COSV61551921; called by muse, mutect2, varscan2
- TMEM43 | c.354C>T p.H118= | Silent (SNP) | VAF 83/179 reads (46%) | catalogued as rs754103544, COSV60145622; called by muse, mutect2, varscan2
- UIMC1 | c.666C>T p.G222= | Silent (SNP) | VAF 16/98 reads (16%) | called by muse, mutect2, varscan2
- UNC13A | c.2304G>T p.T768= | Silent (SNP) | VAF 66/245 reads (27%) | catalogued as COSV53190649; called by muse, mutect2, varscan2
- USP6 | c.1377G>T p.T459= | Silent (SNP) | VAF 177/585 reads (30%) | catalogued as COSV51488666; called by muse, mutect2, varscan2
- VSX2 | c.267G>A p.T89= | Silent (SNP) | VAF 71/264 reads (27%) | catalogued as rs369629867; called by muse, mutect2, varscan2
- ZNF283 | c.240C>T p.I80= | Silent (SNP) | VAF 62/232 reads (27%) | catalogued as rs757130205, COSV60288986, COSV60289087; called by muse, mutect2, varscan2
- ZNF630 | c.450G>A p.E150= | Silent (SNP) | VAF 57/227 reads (25%) | called by muse, mutect2, varscan2
- ZNF717 | c.2010G>A p.T670= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as rs1304007890, COSV68859263; called by mutect2, varscan2
- AC121338.1 | chr12:47904576 C>A | 3'Flank (SNP) | VAF 43/201 reads (21%) | called by muse, mutect2, varscan2
- ASL | c.*44G>A | 3'UTR (SNP) | VAF 88/271 reads (32%) | catalogued as rs760898764; called by muse, mutect2, varscan2
- ATP2A3 | c.*28C>A | 3'UTR (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- BET1P1 | n.18G>T | RNA (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2
- CALM3 | c.3+670T>A | Intron (SNP) | VAF 76/246 reads (31%) | called by muse, mutect2, varscan2
- CHCHD3 | c.170-10106A>C | Intron (SNP) | VAF 111/402 reads (28%) | catalogued as rs753366893; called by muse, mutect2, varscan2
- EYA1 | c.34-48336C>T | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- FANCA | c.-32G>T | 5'UTR (SNP) | VAF 57/190 reads (30%) | called by muse, mutect2, varscan2
- FHL1 | c.*489G>C | 3'UTR (SNP) | VAF 26/77 reads (34%) | called by muse, mutect2, varscan2
- GATA4 | c.-100C>A | 5'UTR (SNP) | VAF 71/316 reads (22%) | called by muse, mutect2, varscan2
- IKBKB | c.1516+10C>T | Intron (SNP) | VAF 93/324 reads (29%) | called by muse, mutect2, varscan2
- IRAG1 | c.67+3239A>C | Intron (SNP) | VAF 3/32 reads (9%) | catalogued as rs1338521804; called by muse, mutect2
- KDM3A | c.*12A>T | 3'UTR (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- KRT8P11 | n.337T>G | RNA (SNP) | VAF 126/402 reads (31%) | called by muse, mutect2, varscan2
- LINC01591 | n.611T>A | RNA (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- LINC02872 | n.379C>A | RNA (SNP) | VAF 25/109 reads (23%) | catalogued as rs539508145; called by muse, mutect2, varscan2
- MYADML | n.919C>A | RNA (SNP) | VAF 135/473 reads (29%) | called by muse, mutect2, varscan2
- NDUFA3 | c.10+28G>T | Intron (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- NFKBIB | c.*47A>T | 3'UTR (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- NPIPA8 | chr16:18340282 G>A | 5'Flank (SNP) | VAF 156/344 reads (45%) | called by muse, mutect2, varscan2
- NPIPB1P | n.180G>T | RNA (SNP) | VAF 78/314 reads (25%) | called by muse, mutect2, varscan2
- NRSN1 | c.*282T>A | 3'UTR (SNP) | VAF 189/309 reads (61%) | called by muse, mutect2, varscan2
- PCNP | c.65-192G>T | Intron (SNP) | VAF 30/136 reads (22%) | called by muse, mutect2, varscan2
- PNKP | c.579-23C>G | Intron (SNP) | VAF 28/389 reads (7%) | called by muse, mutect2
- PORCN | c.-37-22C>T | Intron (SNP) | VAF 48/138 reads (35%) | catalogued as rs1556973470; called by muse, mutect2, varscan2
- PPP3CC | c.372+40C>T | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- PTPN9 | c.528+3921G>T | Intron (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- RORA | c.196+63719A>G | Intron (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- SPATA8 | n.245G>C | RNA (SNP) | VAF 63/198 reads (32%) | catalogued as COSV100138933; called by muse, mutect2, varscan2
- TTN | c.34264+4823G>A | Intron (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- UBBP4 | n.821A>T | RNA (SNP) | VAF 94/430 reads (22%) | catalogued as rs777804180; called by muse, varscan2
- ZNF812P | n.774C>T | RNA (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
